Somatic mutation profile of tumor specimen ALCH-B0CK-TTP1-A (aliquot ALCH-B0CK-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0CK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.6 years (19,593 days).
Specimen ALCH-B0CK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e232b299-a7e4-4ced-afd3-8ba79ff9a6ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CK-NB1-A (Blood Derived Normal), aliquot ALCH-B0CK-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e412c87-5db6-4388-9bbc-39acb6ec4bf1

The open-access MAF lists 59 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 13, Intron 5, Splice Region 2, 3'UTR 1, Nonsense Mutation 1, Splice Site 1, In Frame Del 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 84/646 reads (13%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- CELA3B | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1231345290, COSV100448843; called by muse, mutect2, varscan2
- CEP131 | c.1853G>A p.R618Q (on ENST00000269392 / NM_001319228.2; = p.R615Q on NM_014984.4) | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs375083735; called by muse, mutect2, varscan2
- FAM135B | c.2775G>C p.E925D | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52701879; called by muse, mutect2, varscan2
- FRYL | c.5861G>A p.R1954Q | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.49); catalogued as rs752722074; called by muse, mutect2, varscan2
- FSCN2 | c.1414G>A p.G472S | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as rs908743048, COSV99066061; called by muse, mutect2
- GJA3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs781023239, COSV53834771; called by muse, mutect2
- ITGB2 | c.1579T>A p.S527T (on ENST00000302347; = p.S503T on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs1568882038; called by muse, mutect2
- LCA5L | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55744675; called by muse, mutect2
- LMOD1 | c.434G>A p.S145N | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs1347347707; called by muse, mutect2, varscan2
- MX2 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs747459235; called by muse, mutect2, varscan2
- OPLAH | c.1347C>G p.S449R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV70679457; called by muse, mutect2, varscan2
- OR10C1 | c.703C>T p.R235C (on ENST00000622521; = p.R233C on NM_013941.3) | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs147036236, COSV65822212; called by muse, mutect2, varscan2
- PLPPR4 | c.1954C>G p.P652A | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64565753; called by muse, mutect2, varscan2
- PTPRB | c.2789C>T p.P930L | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1210759908; called by muse, mutect2
- RFPL4AL1 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 25/314 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1402227040; called by muse, mutect2
- RTTN | c.30C>T p.L10= | Splice Region (SNP) | VAF 17/203 reads (8%) | catalogued as rs767295264; called by muse, mutect2
- SFI1 | c.2527C>T p.R843W (on ENST00000400288 / NM_001007467.3; = p.R812W on NM_014775.4) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs367957589; called by muse, mutect2
- SYNE2 | c.16653G>C p.L5551F | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59943643; called by muse, mutect2, varscan2
- SYNE2 | c.16772G>A p.G5591E | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.356); catalogued as rs1207857190; called by muse, mutect2
- TBC1D9 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); catalogued as COSV71307483; called by muse, mutect2
- UNC5A | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99457869; called by muse, mutect2, varscan2
- ZC2HC1A | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as rs775645554, COSV55667219; called by muse, mutect2
- ABCC11 | c.1078_1085delinsAAAAAAAA p.P360_A362delinsKKK | Missense Mutation (ONP) | VAF 6/58 reads (10%) | called by mutect2*, pindel
- BMP2 | c.796A>C p.T266P | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMTR1 | c.1290C>G p.F430L | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2
- CTSD | c.973-5C>G | Splice Region (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- CWH43 | c.44-4_44delinsTTTT p.X15_splice | Splice Site (DEL) | VAF 4/21 reads (19%) | called by pindel, varscan2*
- DBR1 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- DLX4 | c.472C>G p.Q158E (on ENST00000240306 / NM_138281.3; = p.Q86E on NM_001934.3) | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2
- FAT4 | c.14641G>T p.D4881Y | Missense Mutation (SNP) | VAF 27/403 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- FBXO33 | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, mutect2
- MTX1 | c.41C>G p.T14R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.031); called by muse, mutect2
- RELN | c.6370G>C p.D2124H | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RFPL1 | c.740T>A p.I247N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIOK1 | c.330C>A p.D110E | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.024); called by muse, mutect2
- USP10 | c.621G>T p.R207S | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZC3H10 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.221); called by muse, mutect2
- CA10 | c.231C>T p.I77= | Silent (SNP) | VAF 19/258 reads (7%) | catalogued as COSV53379009; called by muse, mutect2
- CDH23 | c.6375C>A p.I2125= | Silent (SNP) | VAF 34/435 reads (8%) | called by muse, mutect2
- CMTR1 | c.1137C>G p.L379= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- DOCK1 | c.2700G>A p.Q900= | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- FAM166B | c.309C>T p.F103= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV63428555; called by muse, mutect2
- FAM50A | c.606C>G p.T202= | Silent (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- LSAMP | c.123C>T p.I41= | Silent (SNP) | VAF 46/431 reads (11%) | catalogued as rs147943673; called by muse, mutect2, varscan2
- OBSCN | c.3450C>T p.G1150= | Silent (SNP) | VAF 13/151 reads (9%) | catalogued as COSV52811183; called by muse, mutect2
- RELA | c.390C>T p.I130= | Silent (SNP) | VAF 34/362 reads (9%) | called by muse, mutect2
- SEPTIN4 | c.114G>A p.V38= | Silent (SNP) | VAF 26/512 reads (5%) | called by muse, mutect2
- SGSM3 | c.1131C>T p.L377= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV50651131; called by muse, mutect2, varscan2
- SOCS5 | c.171T>C p.S57= | Silent (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- ZNF449 | c.429A>G p.L143= | Silent (SNP) | VAF 17/285 reads (6%) | called by muse, mutect2
- COL1A2 | c.3105+47T>C | Intron (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- LRR1 | chr14:49598680 C>A | 5'Flank (SNP) | VAF 27/425 reads (6%) | called by muse, mutect2
- NDUFB1 | c.-184G>C | 5'UTR (SNP) | VAF 47/404 reads (12%) | catalogued as COSV100102627; called by muse, mutect2, varscan2
- PHC2 | c.2423-944_2423-914del | Intron (DEL) | VAF 22/182 reads (12%) | called by mutect2, pindel
- RDX | c.13-399C>T | Intron (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- TOM1 | c.138-162G>C | Intron (SNP) | VAF 28/308 reads (9%) | called by muse, mutect2
- XRCC4 | c.894-42314G>C | Intron (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- ZDHHC3 | c.*6455T>G | 3'UTR (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
